Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB3A, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB3A-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-O-3
Liposarcoma, dedifferentiated
Site: ^{CAF} Retroperitoneum
P48.0
P49.5

Clinical Diagnosis & History:

History of well differentiated liposarcoma with recurrence.

Specimens Submitted:

1: SP: Radical resection right recurrent pelvic liposarcoma with appendix

DIAGNOSIS:

1. SOFT TISSUE, RIGHT PELVIC WITH APPENDIX; RADICAL RESECTION:
- RECURRENT DEDIFFERENTIATED LIPOSARCOMA.
- THE DEDIFFERENTIATED COMPONENT PREDOMINATES AND HAS A HIGH GRADE MYXOFIBROSARCOMA-LIKE APPEARANCE.
- TUMOR SIZE: 26 x 22 x 13.5 CM.
- LARGE AREAS OF NECROSIS ARE NOTED, APPROXIMATELY 30% GROSS ESTIMATE.
- THE TUMOR IS SURROUNDED BY AN INTACT TRANSLUCENT MEMBRANE, WHICH REPRESENTS THE SURGICAL MARGINS.
- TRAUMATIC NEUROMA ADJACENT TO THE SUTURE GRANULOMATA, CONSISTENT WITH PRIOR SURGERY SITE.
- THE APPENDIX IS UNREMARKABLE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh labeled, "Radical resection right recurrent pelvic liposarcoma with appendix" and consists of an unoriented piece of soft tissue mass with peritoneal lining, measuring 26 x 22 x 13.5 cm. The specimen is inked in black at the outer surface, which is represented by a thin translucent membrane. The specimen is serially sectioned to reveal a heterogeneous cut surface, with areas of tan yellow and fatty, areas of tan white and fleshy, areas of tan brown and nodular, areas of tan brown and soft, and areas of tan green necrosis with cystic

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
change (necrosis is approximately 30% of the tumor). The appendix is attached, measuring 3.5 cm in length, 0.5 cm in diameter. Sectioning reveals pinpoint lumen and grossly unremarkable mucosa. A hemorrhagic mesenteric nodule is found, possibly a lymph node, which is bisected and submitted. Photograph is taken. Portion of the tumor is given for TPS. Representative sections are submitted.

Summary of sections:

RS - representative sections

AP appendix, resection margin and the tip

A necrotic nodule

BLN bisected lymph node

Summary of Sections:

Part 1: SP: Radical resection right recurrent pelvic liposarcoma with appendix

Block	Sect.	Site	PCs
1	a		1
1	ap		1
1	bln		1
13	rs		13

** End of Report **

Source: NCI Genomic Data Commons file d071587b-7593-4fb8-8223-9ad54fb05e70 (TCGA-DX-AB3A.EA8AD237-05FE-469D-BBCF-A8BD12CB8701.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).